Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6856, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6856-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted]

Formatted Path Report

[Redacted]	[Redacted]	[Redacted]		
------------	------------	------------	--	--

[page 2 of 3]
	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Right Hemicolectomy Specimen size: Not specified Tumor site: Cecum Tumor size: 6.5 x 7 x 5 cm Tumor features: None specified Histologic type: Mucinous adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--

Source: NCI Genomic Data Commons file ecee8b38-23ae-4bba-b33c-d44f3a69a15d (TCGA-F4-6856.B45764E2-A7CA-47EC-8A4F-D39FD7F190C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).